Somatic mutation profile of tumor specimen TARGET-10-PASXUC-09A (aliquot TARGET-10-PASXUC-09A-01D) from TARGET case TARGET-10-PASXUC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,490 days).
Specimen TARGET-10-PASXUC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ad76d21-5af5-4f84-9e9d-06208fa624c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASXUC-14A (Bone Marrow Normal), aliquot TARGET-10-PASXUC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53a5427b-dd40-4ff8-a623-1bd5ff8484d4

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Intron 7, Silent 6, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, RNA 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs771566403, COSV53125419; called by muse, mutect2, varscan2
- ANKRD17 | c.5936C>T p.T1979M | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.293); catalogued as rs755183443, COSV58221224; called by muse, mutect2, varscan2
- ARAP3 | c.2041G>A p.G681S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1055572281, COSV53351887; called by muse, mutect2
- ATAD2 | c.1646+1G>T p.X549_splice | Splice Site (SNP) | VAF 23/116 reads (20%) | catalogued as COSV54881577; called by muse, mutect2, varscan2
- B3GALT4 | c.725dup p.R243Qfs*108 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | catalogued as rs779828300; called by mutect2, pindel, varscan2
- C5 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV56328408; called by muse, mutect2
- COL23A1 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.454); catalogued as COSV66791690; called by muse, mutect2, varscan2
- CPAMD8 | c.349G>A p.G117S (on ENST00000651564; = p.G70S on NM_015692.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV52235303; called by muse, mutect2, varscan2
- DHX40 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52068087; called by muse, mutect2, varscan2
- ERICH3 | c.1971G>T p.K657N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.605); catalogued as rs780434768, COSV58608779; called by muse, mutect2, varscan2
- ETV6 | c.812G>C p.S271T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as COSV67150603; called by muse, mutect2, varscan2
- FFAR2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs531566827, COSV55832481; called by muse, mutect2, varscan2
- GIMAP4 | c.497A>G p.D166G | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs557887614, COSV55432904; called by muse, mutect2, varscan2
- ITLN2 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs758336172, COSV63537864; called by muse, mutect2, varscan2
- MAGEB17 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1296908545; called by muse, mutect2, varscan2
- MAP7 | c.803C>A p.S268* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV63418630, COSV63420299; called by muse, mutect2, varscan2
- MYH7B | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs773620102, COSV53420113; called by muse, mutect2, varscan2
- NEDD4 | c.1907C>T p.T636I (on ENST00000508342 / NM_001284338.1; = p.T217I on NM_006154.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV59062574; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- PCDH11X | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774847953, COSV53472278; called by muse, mutect2, varscan2
- PLCH2 | c.1790A>C p.E597A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV53944116; called by mutect2, varscan2
- PPARGC1A | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs34129331; called by muse, mutect2, varscan2
- PRRG4 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs765496490, COSV57673005; called by muse, mutect2, varscan2
- RAB40C | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs746975761, COSV50193823; called by muse, mutect2, varscan2
- RASL10B | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.03); catalogued as rs782389253; called by muse, mutect2, varscan2
- RBM12 | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV58292109; called by muse, mutect2, varscan2
- RNF123 | c.718T>G p.S240A | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.535); catalogued as COSV59688084; called by muse, mutect2, varscan2
- ROBO1 | c.2539C>T p.R847* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as rs758742141, COSV71394047; called by muse, mutect2, varscan2
- SH3PXD2A | c.3148C>T p.R1050C (on ENST00000369774 / NM_001365079.1; = p.R1022C on NM_014631.2) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs755681659, COSV60117789; called by muse, mutect2, varscan2
- SLC26A4 | c.1022C>G p.P341R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55917167; called by muse, mutect2, varscan2
- SNED1 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs751755887, COSV60025369; called by muse, mutect2, varscan2
- SPDYE3 | c.1504_1505del p.Q502Dfs*33 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as COSV60107351; called by mutect2, pindel, varscan2
- ZFYVE9 | c.4052T>C p.L1351P | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55094708; called by muse, mutect2, varscan2
- ZNF519 | c.877_878insGG p.K293Rfs*245 | Frame Shift Ins (INS) | VAF 20/114 reads (18%) | catalogued as COSV73913401; called by mutect2, pindel, varscan2
- ZSCAN31 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as rs757653477, COSV60180213; called by muse, mutect2, varscan2
- EHD4 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FDXACB1 | c.762C>A p.G254= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- FUT1 | c.420G>A p.P140= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1411517606, COSV100038186; called by muse, mutect2
- MAML2 | c.1506C>T p.G502= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs774585065, COSV73264163; called by muse, mutect2, varscan2
- NSF | c.2175T>C p.R725= | Silent (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- STAMBP | c.753C>T p.I251= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1218334610, COSV104413250; called by muse, mutect2, varscan2
- VGLL3 | c.972G>A p.P324= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs748049327, COSV68209222; called by muse, mutect2, varscan2
- ANO1 | c.1950+203C>A | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- CFAP46 | c.660+52C>A | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as rs762173559; called by muse, mutect2, varscan2
- DPY19L3 | c.*33C>T | 3'UTR (SNP) | VAF 11/40 reads (28%) | catalogued as rs536657514; called by muse, mutect2, varscan2
- FOSB | c.448-79T>C | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- KCNIP2 | c.765+21C>G | Intron (SNP) | VAF 12/44 reads (27%) | catalogued as COSV53307372; called by muse, mutect2, varscan2
- MCRS1 | c.10+86G>C | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- MGAM | c.4618+11200G>T | Intron (SNP) | VAF 20/31 reads (65%) | called by muse, mutect2, varscan2
- NGDN | c.928+85C>T | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- SSPOP | n.7520C>T | RNA (SNP) | VAF 4/16 reads (25%) | catalogued as rs760377742, COSV100022108; called by muse, varscan2
